Somatic mutation profile of tumor specimen TCGA-KK-A8IM-01A (aliquot TCGA-KK-A8IM-01A-11D-A364-08) from TCGA case TCGA-KK-A8IM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,425 days).
Specimen TCGA-KK-A8IM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d1ef6fa-7a5f-43d1-a2ee-46a0c7e0d4a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IM-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IM-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c0298e4-7d59-4b1a-8954-73d372e08e97

The open-access MAF lists 25 somatic variants for this specimen: 24 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 15, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADIPOQ | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs144526209; called by muse, mutect2, varscan2
- ASTN1 | c.1694G>T p.C565F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99920116; called by muse, mutect2, varscan2
- BCORL1 | c.3509G>C p.G1170A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.053); catalogued as COSV99498214; called by muse, mutect2
- BIVM-ERCC5 | c.532T>G p.Y178D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as COSV99958475; called by muse, mutect2, varscan2
- C2orf16 | c.422A>T p.Y141F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101284327; called by muse, mutect2, varscan2
- CLCN7 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1198692603, COSV99246800; called by muse, mutect2, varscan2
- CLP1 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239674; called by muse, mutect2, varscan2
- CTSO | c.542G>A p.W181* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as COSV101467826; called by muse, mutect2, varscan2
- DCTN4 | c.1169+2T>C p.X390_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101437516; called by muse, mutect2, varscan2
- GAD2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV52150253; called by muse, mutect2
- HNRNPA3 | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101182805; called by muse, mutect2, varscan2
- IL12B | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99180309; called by muse, mutect2, varscan2
- KCNJ6 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 24/193 reads (12%) | catalogued as COSV99898907; called by muse, mutect2, varscan2
- MCTP1 | c.981+1del p.X327_splice | Splice Site (DEL) | VAF 7/53 reads (13%) | catalogued as COSV56506210; called by mutect2, pindel, varscan2
- RAD51B | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1296326210, COSV101184776, COSV66847806; called by muse, mutect2, varscan2
- RYR3 | c.10183C>T p.R3395* (on ENST00000389232; = p.R3396* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV66800780; called by muse, mutect2, varscan2
- SYDE1 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99654509; called by muse, mutect2, varscan2
- TEX14 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777634465, COSV99541145; called by muse, mutect2, varscan2
- UFL1 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs969792177, COSV100989995, COSV65149654; called by muse, mutect2, varscan2
- XKR4 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.572); catalogued as rs761395206, COSV59297915; called by muse, mutect2, varscan2
- ADGRB3 | c.694del p.Q232Rfs*25 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- DDX59 | c.1762del p.E588Nfs*46 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- KIAA0319L | c.3139_3141del p.E1047del | In Frame Del (DEL) | VAF 5/26 reads (19%) | called by pindel, varscan2
- RRM1 | c.2151_2190+9del p.X717_splice | Splice Site (DEL) | VAF 6/67 reads (9%) | called by mutect2, pindel
- SORCS3 | c.1968C>T p.D656= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs372850065; called by muse, mutect2, varscan2
